Somatic mutation profile of tumor specimen TCGA-AB-2871-03A (aliquot TCGA-AB-2871-03A-01W-0732-08) from TCGA case TCGA-AB-2871, project TCGA-LAML (Acute Myeloid Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acute myeloid leukemia without maturation; Tissue or organ of origin: Bone marrow; Age at diagnosis: 51.2 years (18,689 days).
Specimen TCGA-AB-2871-03A: Sample type: Primary Blood Derived Cancer - Peripheral Blood; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Peripheral Blood NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 48efc2f6-afed-4c20-b072-47b8c260ad7c.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-AB-2871-11A (Solid Tissue Normal), aliquot TCGA-AB-2871-11A-01W-0732-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/1f6e20a1-b4f1-47c0-90ff-ed20a45e0f4d

The open-access MAF lists 16 somatic variants for this specimen: 15 protein-altering or splice-affecting, 1 silent.
By variant classification: Missense Mutation 12, Nonsense Mutation 1, Silent 1, Frame Shift Ins 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NPM1 | c.860_863dup p.W288Cfs*12 | Frame Shift Ins (INS) | VAF 17/72 reads (24%) | catalogued as rs587776806, COSV51548899, COSV51555098, COSV51559390, COSV51564309; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- PTPN11 | c.1529A>T p.Q510L | Missense Mutation (SNP) | VAF 239/1237 reads (19%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as CM043070, CM052358, COSV61008620; called by muse, mutect2, varscan2
- ATG14 | c.638C>T p.T213M | Missense Mutation (SNP) | VAF 26/128 reads (20%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.631); catalogued as rs140426113; called by muse, mutect2, varscan2
- BEND3 | c.1871G>T p.R624L | Missense Mutation (SNP) | VAF 2/14 reads (14%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.859); catalogued as COSV64681621; called by muse, mutect2
- COL12A1 | c.4015G>T p.D1339Y | Missense Mutation (SNP) | VAF 38/191 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV59394987; called by muse, mutect2, varscan2
- ELF4 | c.800G>A p.R267Q | Missense Mutation (SNP) | VAF 179/407 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs756180544, COSV57452377; called by muse, mutect2, varscan2
- HEATR4 | c.403G>A p.A135T | Missense Mutation (SNP) | VAF 32/156 reads (21%) | SIFT tolerated (0.18); PolyPhen benign (0.084); catalogued as rs376151634; called by muse, mutect2, varscan2
- KCNJ6 | c.668G>A p.R223Q | Missense Mutation (SNP) | VAF 18/84 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55713516, COSV99900885; called by muse, mutect2, varscan2
- LRFN3 | c.1649C>T p.S550L | Missense Mutation (SNP) | VAF 16/95 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.656); catalogued as COSV55817224, COSV55817686; called by muse, mutect2, varscan2
- NEB | c.13720C>A p.Q4574K | Missense Mutation (SNP) | VAF 36/130 reads (28%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.968); catalogued as COSV51226724; called by muse, mutect2, varscan2
- PIP4P2 | c.700G>A p.G234R | Missense Mutation (SNP) | VAF 43/208 reads (21%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as rs1300068272, COSV53438490; called by muse, mutect2, varscan2
- RAP1GDS1 | c.196G>A p.A66T (on ENST00000408927 / NM_001100427.2; = p.A67T on NM_021159.5) | Missense Mutation (SNP) | VAF 47/219 reads (21%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.628); catalogued as rs773990174, COSV52786842; called by muse, mutect2, varscan2
- THRAP3 | c.2509C>T p.R837* | Nonsense Mutation (SNP) | VAF 21/139 reads (15%) | catalogued as COSV63567258; called by muse, mutect2, varscan2
- VPS13C | c.9145A>G p.I3049V (on ENST00000644861 / NM_020821.3; = p.I3006V on NM_017684.5) | Missense Mutation (SNP) | VAF 34/136 reads (25%) | SIFT tolerated (0.21); PolyPhen benign (0.074); catalogued as rs781035830, COSV51165792; called by muse, varscan2
- NFIX | c.1161_1164del p.T388Sfs*12 | Frame Shift Del (DEL) | VAF 10/61 reads (16%) | called by mutect2, pindel, varscan2
- PCDHB12 | c.1299C>T p.T433= | Silent (SNP) | VAF 36/191 reads (19%) | catalogued as rs782127065, COSV53394688, COSV99507215; called by muse, mutect2, varscan2
